FM case AD14606 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Vulva.
https://portal.gdc.cancer.gov/cases/cc5030e5-010b-4703-84ac-7b5d04bf6cca

Female, 58.2 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the vulva; primary biopsied or resected from the vulva. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
